Somatic mutation profile of tumor specimen TCGA-WQ-AB4B-01A (aliquot TCGA-WQ-AB4B-01A-11D-A40P-10) from TCGA case TCGA-WQ-AB4B, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 62.3 years (22,769 days).
Specimen TCGA-WQ-AB4B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b765c46-ef3c-4ed9-9899-a896dcb7db1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WQ-AB4B-10A (Blood Derived Normal), aliquot TCGA-WQ-AB4B-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29dd2e30-2a5e-4aee-841c-0a16ab148d70

The open-access MAF lists 79 somatic variants for this specimen: 60 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 18, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 2, In Frame Del 2, Splice Region 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRE3 | c.412A>C p.K138Q | Missense Mutation (SNP) | VAF 5/113 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.041); catalogued as COSV99506328; called by muse, mutect2
- ALB | c.1100T>C p.V367A | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs918646680, COSV99891664; called by muse, mutect2, varscan2
- ANGPT1 | c.830G>T p.R277I | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV52454136; called by muse, mutect2
- ANKRD44 | c.1317G>A p.R439= | Splice Region (SNP) | VAF 10/71 reads (14%) | catalogued as COSV99985286; called by muse, mutect2, varscan2
- ANKRD55 | c.653A>C p.H218P | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100591448; called by muse, mutect2, varscan2
- AP2B1 | c.717-1G>A p.X239_splice | Splice Site (SNP) | VAF 59/190 reads (31%) | catalogued as COSV99251344; called by muse, mutect2, varscan2
- ATP13A3 | c.3344A>G p.Y1115C | Missense Mutation (SNP) | VAF 30/620 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs1242455481, COSV99757287; called by muse, mutect2
- ATRNL1 | c.3684G>A p.M1228I | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100371357; called by muse, mutect2, varscan2
- BAIAP3 | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1202761235, COSV99136280; called by muse, mutect2, varscan2
- CA14 | c.705G>T p.Q235H | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV99354435; called by muse, mutect2
- CCT8L2 | c.1492A>G p.I498V | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs778469756, COSV100742841; called by muse, mutect2, varscan2
- CDH17 | c.51+2T>A p.X17_splice | Splice Site (SNP) | VAF 138/225 reads (61%) | catalogued as COSV99217568; called by muse, varscan2
- CDKN2AIP | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 36/150 reads (24%) | catalogued as COSV100187643, COSV56627264; called by muse, mutect2, varscan2
- COG3 | c.1732C>A p.Q578K | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV100596588, COSV63072056; called by muse, mutect2
- COL12A1 | c.5329A>G p.S1777G | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.359); catalogued as COSV100486166; called by muse, mutect2, varscan2
- DOCK2 | c.5279C>A p.T1760N | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as COSV99913315; called by muse, varscan2
- DPP4 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as rs779450801, COSV100858921; called by muse, mutect2, varscan2
- DPP6 | c.1987C>T p.R663C (on ENST00000377770 / NM_001364500.2; = p.R601C on NM_001936.5) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1443134542, COSV59600522; called by muse, mutect2, varscan2
- DUOX2 | c.2598G>A p.M866I | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101199798; called by muse, mutect2, varscan2
- FAM110D | c.120G>T p.E40D | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV100957632; called by muse, mutect2, varscan2
- FOXI2 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV100511029, COSV59094186; called by muse, mutect2
- IGHV3-66 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 5/115 reads (4%) | catalogued as rs1555573067; called by muse, mutect2
- IPP | c.809A>C p.K270T | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV100739622; called by muse, mutect2, varscan2
- LGR6 | c.2252A>G p.Y751C (on ENST00000367278 / NM_001017403.1; = p.Y699C on NM_021636.3) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV99707266; called by muse, mutect2, varscan2
- LRPPRC | c.2875T>C p.Y959H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as COSV99580879; called by muse, mutect2, varscan2
- LRRC7 | c.4256T>C p.M1419T (on ENST00000651989 / NM_001370785.2; = p.M1339T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV99227766; called by muse, mutect2
- MUC5B | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101500455, COSV71594317; called by muse, mutect2, varscan2
- MUC6 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756600864, COSV101424648; called by muse, mutect2, varscan2
- MYO9A | c.248T>G p.V83G | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100613790; called by muse, mutect2, varscan2
- NCAPD3 | c.3968G>T p.G1323V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as COSV101592170; called by muse, mutect2, varscan2
- OR6C4 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV101263154; called by muse, mutect2, varscan2
- PARP6 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV53001975, COSV99536125; called by muse, mutect2, varscan2
- PDHA2 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV99756991; called by muse, mutect2, varscan2
- PKHD1 | c.2417T>C p.V806A | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.883); catalogued as COSV61864047; called by muse, mutect2
- PRDM13 | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100980536; called by muse, mutect2, varscan2
- PREX1 | c.2770G>T p.D924Y | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100906490; called by muse, varscan2
- RAPGEF2 | c.4213G>A p.G1405S | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.984); catalogued as rs1220140533, COSV100031315, COSV52427273; called by muse, mutect2, varscan2
- SOX9 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV99818532; called by muse, mutect2, varscan2
- TADA1 | c.892G>C p.A298P | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100902330; called by muse, mutect2, varscan2
- TBC1D9B | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1156632138, COSV100783560; called by muse, mutect2, varscan2
- TOPORS | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV100745187; called by muse, mutect2, varscan2
- TPPP | c.214C>A p.H72N | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV100862848; called by muse, mutect2, varscan2
- TRIM32 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100528460; called by muse, mutect2, varscan2
- TRPM3 | c.2944A>T p.I982F (on ENST00000357533 / NM_001366142.2; = p.I825F on NM_020952.6) | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100677663, COSV62587028; called by muse, mutect2, varscan2
- TSHZ2 | c.812C>A p.A271D | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61590070; called by muse, mutect2
- U2AF2 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100454309; called by muse, mutect2, varscan2
- UNK | c.157T>C p.C53R | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99505189; called by muse, mutect2, varscan2
- VSTM1 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as COSV100618820, COSV58075639; called by muse, mutect2, varscan2
- WWP1 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV99616641; called by muse, mutect2, varscan2
- ZNF100 | c.1232A>T p.N411I | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as rs546924864, COSV99974120; called by muse, varscan2
- ZNF318 | c.5807G>A p.R1936K | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); catalogued as COSV100546311; called by muse, mutect2, varscan2
- ZNF665 | c.1451A>G p.K484R (on ENST00000600412; = p.K549R on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV101128535; called by muse, mutect2, varscan2
- ALB | c.254del p.N85Ifs*56 | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | called by mutect2, pindel, varscan2
- MAPK15 | c.6C>A p.C2* | Nonsense Mutation (SNP) | VAF 10/313 reads (3%) | called by muse, mutect2
- NKX2-2 | c.318_332del p.S107_S111del | In Frame Del (DEL) | VAF 24/56 reads (43%) | called by mutect2, pindel, varscan2
- NLGN4Y | c.1195_1215del p.V399_N405del | In Frame Del (DEL) | VAF 62/170 reads (36%) | called by pindel, varscan2
- TBX18 | c.1528_1535del p.T510Dfs*7 | Frame Shift Del (DEL) | VAF 30/129 reads (23%) | called by mutect2, pindel, varscan2
- UPF3B | c.738dup p.I247Yfs*19 | Frame Shift Ins (INS) | VAF 27/55 reads (49%) | called by mutect2, pindel, varscan2
- ZNF800 | c.1185del p.G396Afs*11 | Frame Shift Del (DEL) | VAF 23/153 reads (15%) | called by mutect2, pindel, varscan2
- ANTXR1 | c.1161C>T p.G387= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs762651259, COSV58016294; called by muse, mutect2, varscan2
- APOBEC3G | c.942C>T p.I314= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as COSV101349088; called by muse, mutect2, varscan2
- CCDC60 | c.1626C>T p.P542= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100555312; called by muse, mutect2, varscan2
- COL22A1 | c.4746C>T p.G1582= | Silent (SNP) | VAF 32/327 reads (10%) | catalogued as COSV100278973; called by muse, mutect2, varscan2
- DOCK2 | c.5280C>A p.T1760= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as rs1453239969, COSV99913316; called by muse, varscan2
- DUOX1 | c.1431C>A p.S477= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV100368103; called by muse, mutect2, varscan2
- GABRA5 | c.1209C>A p.V403= | Silent (SNP) | VAF 173/405 reads (43%) | catalogued as COSV100164788, COSV100165355; called by muse, mutect2, varscan2
- HMCN1 | c.8550T>A p.A2850= | Silent (SNP) | VAF 30/203 reads (15%) | catalogued as COSV99630894; called by muse, mutect2, varscan2
- MYT1 | c.252C>T p.D84= | Silent (SNP) | VAF 49/175 reads (28%) | catalogued as rs150526675, COSV60517235; called by muse, mutect2, varscan2
- PADI2 | c.957G>A p.L319= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as rs141844952; called by muse, mutect2, varscan2
- PREX1 | c.2721G>A p.L907= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV100906492; called by muse, varscan2
- PREX1 | c.2613G>A p.E871= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV100906494; called by muse, mutect2, varscan2
- SIAH2 | c.405G>A p.L135= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV100469310; called by muse, mutect2, varscan2
- TCIRG1 | c.1509C>T p.N503= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as rs754235952, COSV55837376; ClinVar: likely benign; called by muse, mutect2, varscan2
- TOGARAM1 | c.3498A>G p.E1166= | Silent (SNP) | VAF 36/158 reads (23%) | catalogued as COSV100818111; called by muse, mutect2, varscan2
- ZAN | c.90C>G p.R30= | Silent (SNP) | VAF 44/395 reads (11%) | catalogued as COSV100769850; called by muse, mutect2, varscan2
- ZFP36L1 | c.972A>C p.S324= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100322756; called by muse, mutect2, varscan2
- ZNF91 | c.3102C>T p.S1034= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100322931; called by muse, mutect2
- ZNF280B | c.*2T>G | 3'UTR (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100840337; called by muse, mutect2, varscan2
